Somatic mutation profile of tumor specimen TCGA-EY-A3QX-01A (aliquot TCGA-EY-A3QX-01A-11D-A228-09) from TCGA case TCGA-EY-A3QX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 64.8 years (23,663 days).
Specimen TCGA-EY-A3QX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5171c0a0-3657-49c8-a38e-83b4b7403335.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A3QX-10A (Blood Derived Normal), aliquot TCGA-EY-A3QX-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4be55683-5d87-45a8-87b0-608fd2b8f02e

The open-access MAF lists 64 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 17, Nonsense Mutation 7, Frame Shift Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRT | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | hotspot (GDC flag); catalogued as COSV61965733, COSV62024591; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 24/29 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL4 | c.1994G>T p.C665F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100875968; called by muse, mutect2, varscan2
- AKAP12 | c.3265G>T p.E1089* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53574743, COSV99483265; called by muse, mutect2, varscan2
- ANO1 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV100304020; called by muse, mutect2, varscan2
- ANO1 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100304021; called by muse, mutect2, varscan2
- APOBR | c.3250C>T p.R1084W (on ENST00000431282; = p.R1093W on NM_018690.4) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765766783, COSV100112583; called by muse, mutect2, varscan2
- BRAP | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554150; called by muse, mutect2, varscan2
- CD1A | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs140989108, COSV56860759; called by muse, mutect2, varscan2
- CDH7 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775706781, COSV59884116; called by muse, mutect2, varscan2
- CEP97 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100511759; called by muse, mutect2, varscan2
- CILP | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99973426; called by muse, mutect2, varscan2
- COL4A1 | c.3395A>G p.K1132R | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV101011188; called by muse, mutect2, varscan2
- DCAF13 | c.752C>G p.A251G | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV99885343; called by muse, mutect2
- DNAH8 | c.4043T>C p.L1348P | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283735349, COSV100545439; called by muse, mutect2, varscan2
- DYNC2H1 | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV100518611, COSV62103817; called by muse, mutect2, varscan2
- ELMO1 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs867300194, COSV60298876; called by muse, mutect2, varscan2
- FBXL13 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100501639, COSV57545710; called by muse, mutect2
- HEPACAM2 | c.1334C>G p.T445R (on ENST00000394468 / NM_001039372.4; = p.T433R on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100506572; called by muse, mutect2, varscan2
- HS6ST1 | c.899C>G p.T300R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99389614; called by muse, mutect2, varscan2
- KIF13B | c.3592G>A p.A1198T | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV101580690; called by muse, mutect2, varscan2
- KIF27 | c.499+1G>T p.X167_splice | Splice Site (SNP) | VAF 28/42 reads (67%) | catalogued as COSV99926989; called by muse, mutect2, varscan2
- MAP3K5 | c.1825G>T p.V609F | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100752836; called by muse, mutect2, varscan2
- MYO1A | c.2551A>T p.S851C | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100270951; called by muse, mutect2, varscan2
- NOM1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV99315745; called by muse, mutect2, varscan2
- NUP214 | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV100845293; called by muse, mutect2, varscan2
- NWD1 | c.2086C>G p.L696V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.3); catalogued as rs761871402, COSV100342641; called by muse, mutect2, varscan2
- NXF3 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as rs867932421, COSV101221974; called by muse, mutect2, varscan2
- PCDHA10 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs773891459, COSV56516274; called by muse, mutect2, varscan2
- PKHD1 | c.9578T>A p.V3193D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100583161; called by muse, mutect2, varscan2
- PRDM9 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57011441, COSV57013096; called by muse, mutect2, varscan2
- PRICKLE3 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99602910; called by muse, mutect2, varscan2
- PSMB3 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs771796105; called by muse, varscan2
- PTPRH | c.360C>A p.N120K | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV99671018; called by muse, mutect2, varscan2
- RABGGTA | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368437109; called by muse, mutect2, varscan2
- RYR3 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs558475472, COSV101212797; called by muse, mutect2, varscan2
- SMC1A | c.3533C>G p.S1178W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100447399; called by muse, mutect2, varscan2
- SNPH | c.1116G>C p.E372D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.831); catalogued as COSV100378180; called by muse, mutect2, varscan2
- SYAP1 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as rs775362718, COSV101204948; called by muse, mutect2, varscan2
- TMEM161A | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99365493; called by muse, mutect2, varscan2
- TRPM1 | c.3740C>T p.S1247F | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99855967; called by muse, mutect2, varscan2
- ZMIZ1 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs1196469674, COSV57895107; called by muse, mutect2, varscan2
- ZNF608 | c.3449C>T p.S1150L | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs374429838; called by muse, mutect2, varscan2
- ZNF808 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 36/54 reads (67%) | catalogued as COSV100707943, COSV63119379; called by muse, mutect2, varscan2
- SSR3 | c.212_213del p.Y71Ffs*35 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by pindel, varscan2
- TREML1 | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- AHNAK2 | c.1413C>T p.T471= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs376099003; called by muse, mutect2, varscan2
- ARHGAP4 | c.300G>A p.L100= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100604061; called by muse, mutect2, varscan2
- CATSPER4 | c.1377T>A p.S459= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV100128386; called by muse, mutect2, varscan2
- CHAT | c.1054C>T p.L352= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100340180; called by muse, mutect2, varscan2
- CYP2B6 | c.870C>G p.L290= | Silent (SNP) | VAF 26/37 reads (70%) | catalogued as COSV100137572, COSV57844902; called by muse, mutect2, varscan2
- EXD3 | c.1581C>G p.G527= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100573714; called by muse, mutect2, varscan2
- FAM237A | c.324T>C p.S108= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV69305062; called by muse, mutect2, varscan2
- GPC3 | c.867G>C p.V289= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100892975; called by muse, mutect2, varscan2
- MCC | c.222G>A p.T74= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs779467330, COSV100202621; called by muse, mutect2, varscan2
- OBSL1 | c.5376G>A p.A1792= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99522878; called by muse, varscan2
- PHLDB2 | c.1629A>G p.L543= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101208530; called by muse, mutect2, varscan2
- RAB6D | c.666T>C p.P222= | Silent (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- SASH3 | c.699C>T p.P233= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs768262427, COSV63555672; called by muse, mutect2, varscan2
- SELE | c.453C>T p.H151= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs758766240, COSV100324770; called by muse, mutect2, varscan2
- SFI1 | c.1005C>T p.S335= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV101192100; called by muse, mutect2, varscan2
- SH3KBP1 | c.1869C>T p.I623= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs1288105396, COSV65646935, COSV65648787; called by muse, mutect2, varscan2
- TSGA10IP | c.1026G>A p.K342= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV101598408; called by muse, mutect2, varscan2
- ANKRD33 | c.664+58C>T | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100001316; called by muse, mutect2, varscan2
